Surgical pathology report (de-identified scan), TCGA case TCGA-A6-6780, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-6780-01A (Primary Tumor).

[page 1 of 2]
© 2006 The Authors

© 2006 The Authors

████████████████████

████████████████████

Received fresh labeled "right colon" is a previously unopened, 12 cm segment of proximal right colon with attached 6 cm of distal ileum surfaced by smooth to scabrous tan-pink serosa with a moderate amount of attached mesocolon, mesentery and unremarkable omentum. An unremarkable 6.6 cm appendix averaging 0.5 cm in diameter is present. The proximal and distal margins measure 2.8 and 5 cm in circumference respectively. On opening, there is a nearly circumferential, 10.8 x 8 cm partially necrotic dusky tan-gray-red tumor mass, 4 cm distal to the ileocecal valve. On sectioning, the tumor has a maximum thickness of 2.4 cm, grossly extending into the muscularis to within 1.1 cm of the inked free radial serosal surface. The ileal and remaining colonic mucosa is unremarkable, glistening tan-pink with regular folds and the walls average 0.5 cm in thickness. Several slightly rubbery pale tan-white tissues in keeping with lymph nodes measuring up to 1.4 cm in greatest dimension are recovered from the attached mesocolon and mesentery. Representative sections are submitted in 15 blocks as labeled.

114

Histologic type: Adenocarcinoma with mucinous differentiation
Histologic grade: Moderately differentiated
Primary tumor (pT): Extends through muscularis propria (pT3)
Proximal margin: Not involved
Distal margin: Not involved
Circumferential (radial) margin: Not involved
Vascular invasion: Not identified
Regional lymph nodes (pN): No evidence of metastasis in 18 nodes (pN0)
Non-lymph node pericolic tumor: Not identified
Distant metastasis (pM): Cannot be evaluated by this specimen (pMX)
Other findings: None

[page 2 of 2]
[REDACTED]

DIAGNOSIS

Right colon, resection:

Adenocarcinoma, moderately differentiated, with mucinous
differentiation, 10.8 cm with invasion through the
muscularis propria.

Surgical margins uninvolved.

No evidence of metastasis in 18 lymph nodes (0/18).

Appendix, appendectomy:

No pathologic diagnosis.

[REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 130b59fa-8aad-43cc-9ec9-16d4d26473f5 (TCGA-A6-6780.B3B3707C-E311-4A38-A8A3-E8F8BBA675AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).